Somatic mutation profile of tumor specimen C3N-01876-01 (aliquot CPT0117440006) from CPTAC case C3N-01876, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 65.2 years (23,808 days).
Specimen C3N-01876-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f6d0eb6-5fb3-4515-bd05-0dfe9dc566ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01876-31 (Blood Derived Normal), aliquot CPT0117500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5480e5d-d04c-46fe-8118-3c39786270d2

The open-access MAF lists 1,565 somatic variants for this specimen: 1,092 protein-altering or splice-affecting, 279 silent, 194 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 764, Silent 279, Frame Shift Del 195, Intron 95, Nonsense Mutation 44, Frame Shift Ins 39, 3'UTR 35, 5'UTR 24, RNA 20, Splice Site 17, Splice Region 17, 5'Flank 17.

Variants (750 of 1,565; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7B | c.3007G>A p.A1003T | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201497300, CM980180; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 34/134 reads (25%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- CTNNB1 | c.97T>G p.S33A | Missense Mutation (SNP) | VAF 82/295 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB4 | c.3823C>T p.R1275W | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs397514263, CM1311194, COSV61470692; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ESR1 | c.1613A>G p.D538G | Missense Mutation (SNP) | VAF 206/586 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52781024; called by muse, mutect2, varscan2
- FANCI | c.3853C>T p.R1285* (on ENST00000310775 / NM_001376911.1; = p.R1225* on NM_018193.3) | Nonsense Mutation (SNP) | VAF 85/262 reads (32%) | catalogued as rs121918164, CM074782, CM125195; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GJA8 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 87/582 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs80358205, CM065224; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 36/120 reads (30%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.4204C>T p.Q1402* | Nonsense Mutation (SNP) | VAF 49/156 reads (31%) | catalogued as rs1555195442, COSV56443229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 46/158 reads (29%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, varscan2
- MOCS2 | c.65dup p.L23Ifs*5 | Frame Shift Ins (INS) | VAF 44/162 reads (27%) | catalogued as rs398122799; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1397_1399del p.L466del (on ENST00000521381 / NM_181523.3; = p.L196del on NM_181504.4) | In Frame Del (DEL) | VAF 16/40 reads (40%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 57/161 reads (35%) | catalogued as rs786204934, CM110145, COSV64289396, COSV64297896; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | hotspot (GDC flag); catalogued as rs121909231, CM971278, COSV64288687, COSV64297951; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- SI | c.1859T>C p.L620P | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912613, CM035081, COSV52305106; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPART | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 74/255 reads (29%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- TBCK | c.1370dup p.N457Kfs*10 (on ENST00000273980 / NM_001163436.4; = p.N394Kfs*10 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 18/66 reads (27%) | catalogued as rs746860249; ClinVar: pathogenic; called by mutect2, varscan2
- A3GALT2 | c.235del p.A79Lfs*27 | Frame Shift Del (DEL) | VAF 98/367 reads (27%) | catalogued as rs770563385; called by mutect2, pindel, varscan2
- ABCA12 | c.4637G>A p.R1546H (on ENST00000272895 / NM_173076.3; = p.R1228H on NM_015657.3) | Missense Mutation (SNP) | VAF 106/263 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1274612827, COSV55956227, COSV55978034; called by muse, mutect2, varscan2
- ABCB6 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769981173; called by muse, mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 54/166 reads (33%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABCG1 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs145438298; called by muse, mutect2, varscan2
- ABHD2 | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs984535369; called by muse, mutect2
- ABR | c.2526dup p.I843Hfs*46 (on ENST00000302538 / NM_021962.5; = p.I806Hfs*46 on NM_001092.5) | Frame Shift Ins (INS) | VAF 66/222 reads (30%) | catalogued as rs750897785; called by mutect2, varscan2
- AC104452.1 | c.1227G>A p.M409I | Missense Mutation (SNP) | VAF 136/368 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); catalogued as COSV55534407; called by muse, mutect2, varscan2
- ACTL8 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 145/403 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs765706861, COSV100958688; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 32/108 reads (30%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM29 | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs1181975275; called by muse, mutect2, varscan2
- ADAMTS7 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 29/510 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746705132, COSV66307082; called by muse, mutect2
- ADAMTSL1 | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 14/162 reads (9%) | catalogued as rs761956033, COSV52815302; called by muse, mutect2
- ADCY5 | c.3212C>T p.A1071V | Missense Mutation (SNP) | VAF 123/385 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1395773373, COSV100567301; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745856523, COSV58443114; called by muse, mutect2, varscan2
- ADGRV1 | c.16504G>A p.V5502M | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV67990071; called by muse, mutect2
- ADRA2A | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1284779509; called by muse, mutect2, varscan2
- AGAP3 | c.67del p.Q23Sfs*31 (on ENST00000622464; = p.Q59Sfs*31 on NM_031946.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/125 reads (34%) | catalogued as rs1554459038; called by mutect2, pindel, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 74/200 reads (37%) | catalogued as rs748399150; called by mutect2, varscan2
- AKAP11 | c.5600T>A p.V1867E | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1448519907; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP8 | c.369G>A p.E123= | Splice Region (SNP) | VAF 11/83 reads (13%) | catalogued as rs1489784994; called by muse, mutect2
- AL136295.3 | c.523del p.G175Afs*15 | Frame Shift Del (DEL) | VAF 66/185 reads (36%) | catalogued as rs760463204; called by mutect2, pindel, varscan2
- ALOX12 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.035); catalogued as rs758433028, COSV52351350; called by muse, mutect2, varscan2
- ALOX12B | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 23/565 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1356879129; called by muse, mutect2
- ALS2 | c.3047dup p.Y1017Lfs*5 | Frame Shift Ins (INS) | VAF 138/474 reads (29%) | catalogued as rs538311710; called by mutect2, pindel, varscan2
- AMY2B | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 97/327 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV100796310; called by muse, mutect2, varscan2
- ANAPC1 | c.3131C>T p.A1044V | Missense Mutation (SNP) | VAF 19/532 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs1342539747; called by muse, mutect2
- ANK2 | c.972del p.L325Cfs*24 | Frame Shift Del (DEL) | VAF 102/373 reads (27%) | catalogued as COSV100001787; called by mutect2, pindel, varscan2
- ANKRD35 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 16/290 reads (6%) | catalogued as rs587593514; called by muse, mutect2
- ANO2 | c.2363C>T p.P788L (on ENST00000356134 / NM_001278597.3; = p.P792L on NM_001278596.3) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370114605; called by muse, mutect2, varscan2
- APLN | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 99/290 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758766922, COSV100278253; called by muse, mutect2, varscan2
- APOBEC3D | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs763176347; called by muse, mutect2, varscan2
- APPL1 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769152501; called by muse, mutect2, varscan2
- ARHGAP45 | c.842del p.G281Afs*16 | Frame Shift Del (DEL) | VAF 58/178 reads (33%) | catalogued as COSV57429840; called by mutect2, pindel, varscan2
- ARHGAP6 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 108/313 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV61632701; called by muse, mutect2, varscan2
- ARHGEF10 | c.2210C>T p.A737V (on ENST00000398564; = p.A712V on NM_014629.4) | Missense Mutation (SNP) | VAF 123/409 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs201394769; called by muse, mutect2, varscan2
- ARMCX1 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.023); catalogued as rs1556027290; called by muse, mutect2
- ASCL4 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 120/381 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as rs761289333, COSV60817002; called by muse, mutect2, varscan2
- ATF7IP | c.3562C>T p.R1188* | Nonsense Mutation (SNP) | VAF 82/245 reads (33%) | catalogued as COSV99661506; called by muse, mutect2, varscan2
- ATP12A | c.342dup p.F115Vfs*64 | Frame Shift Ins (INS) | VAF 36/132 reads (27%) | catalogued as rs35191129; called by mutect2, varscan2
- BACH1 | c.133T>C p.F45L | Missense Mutation (SNP) | VAF 15/436 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54517830; called by muse, mutect2
- BEST3 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs779770948; called by muse, mutect2
- BRINP1 | c.1946A>G p.Y649C | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV56296750; called by muse, mutect2
- BRINP2 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 77/525 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1218674798; called by muse, mutect2, varscan2
- BTN3A3 | c.832del p.I278Lfs*13 | Frame Shift Del (DEL) | VAF 59/213 reads (28%) | catalogued as rs1295798865; called by mutect2, pindel, varscan2
- C17orf107 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 150/410 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.047); catalogued as rs1304429225; called by muse, mutect2, varscan2
- C19orf44 | c.1514T>C p.V505A | Missense Mutation (SNP) | VAF 22/528 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1318307777; called by muse, mutect2
- CACNA1A | c.5947C>T p.R1983C | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs772489659; called by muse, mutect2, varscan2
- CACNA1F | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 165/473 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs782123232; called by muse, mutect2, varscan2
- CAPRIN2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51833997; called by muse, mutect2, varscan2
- CARD8 | c.266dup p.Q90Pfs*4 (on ENST00000651546 / NM_001184900.3; = p.Q40Pfs*4 on NM_014959.5 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 39/133 reads (29%) | catalogued as rs769053445; called by mutect2, pindel, varscan2
- CASP7 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs555949483, COSV61883167; called by muse, mutect2, varscan2
- CASS4 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs891477283, COSV64386769; called by muse, mutect2
- CC2D1A | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs201665162; called by muse, mutect2, varscan2
- CCDC150 | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as rs1391938379, COSV55874072; called by muse, mutect2, varscan2
- CCDC50 | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs939758413, COSV66669506; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC88C | c.1318T>C p.S440P | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs781063694; called by muse, mutect2, varscan2
- CCNH | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761675040, COSV99907148; called by mutect2, varscan2
- CCR2 | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 84/316 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.146); catalogued as COSV52750384; called by muse, mutect2, varscan2
- CCS | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371247817; called by muse, mutect2, varscan2
- CD1A | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as rs150169121; called by muse, mutect2, varscan2
- CDK2 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 161/450 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762222976, COSV57187619; called by muse, mutect2, varscan2
- CEBPZ | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99135423; called by muse, mutect2, varscan2
- CFAP44 | c.2665dup p.S889Ffs*2 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | catalogued as rs776033769; called by mutect2, pindel, varscan2
- CFAP45 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 148/944 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV63649674; called by muse, mutect2, varscan2
- CFAP45 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 52/608 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as COSV63647956; called by muse, mutect2
- CILP2 | c.1922G>A p.G641D | Missense Mutation (SNP) | VAF 104/341 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420415587; called by muse, mutect2, varscan2
- CLCA4 | c.544dup p.I182Nfs*13 | Frame Shift Ins (INS) | VAF 23/107 reads (21%) | catalogued as rs760255767; called by mutect2, varscan2
- CLCN2 | c.1142dup p.G382Wfs*21 | Frame Shift Ins (INS) | VAF 136/468 reads (29%) | catalogued as rs1217596296; called by mutect2, pindel, varscan2
- CLCN4 | c.1159A>G p.N387D | Missense Mutation (SNP) | VAF 73/245 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV66466041; called by muse, mutect2, varscan2
- CLCN5 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 24/370 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56587178; called by muse, mutect2
- CLDN15 | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 177/545 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as rs748981078; called by muse, mutect2, varscan2
- CLDN19 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.322); catalogued as rs571067526, COSV56418923; called by muse, mutect2, varscan2
- CLDN9 | c.537del p.L180Sfs*196 | Frame Shift Del (DEL) | VAF 28/100 reads (28%) | catalogued as rs763852712; called by mutect2, pindel, varscan2
- CMPK2 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs745874619, COSV56774020, COSV56775252; called by muse, mutect2, varscan2
- CNTNAP1 | c.2798C>T p.A933V | Missense Mutation (SNP) | VAF 23/363 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs777042333, COSV104390772; called by muse, mutect2
- CNTNAP1 | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 78/209 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377605075; called by muse, mutect2, varscan2
- CNTNAP3 | c.1856T>A p.L619H | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as COSV52675582; called by muse, mutect2
- COL17A1 | c.3383C>T p.A1128V | Missense Mutation (SNP) | VAF 132/477 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.058); catalogued as rs747491139; called by muse, mutect2, varscan2
- COL21A1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs1018709010; called by muse, mutect2, varscan2
- COL28A1 | c.2691del p.V898Wfs*18 | Frame Shift Del (DEL) | VAF 40/164 reads (24%) | catalogued as rs766010947; called by mutect2, varscan2
- COL6A3 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 125/391 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV55093669; called by muse, mutect2, varscan2
- COL6A5 | c.2481del p.K827Nfs*7 | Frame Shift Del (DEL) | VAF 34/115 reads (30%) | catalogued as rs1222064379; called by mutect2, pindel, varscan2
- COL9A2 | c.104del p.P35Rfs*51 | Frame Shift Del (DEL) | VAF 61/219 reads (28%) | catalogued as rs761125486; called by mutect2, pindel, varscan2
- COPB2 | c.2271G>C p.L757F | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs141870357; called by muse, mutect2, varscan2
- COPG1 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 124/385 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.151); catalogued as rs767131343, COSV100135629; called by muse, mutect2, varscan2
- CORIN | c.1774T>C p.C592R | Missense Mutation (SNP) | VAF 85/296 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149916577; called by muse, mutect2
- COX14 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs141173025; called by muse, mutect2, varscan2
- CREBBP | c.6281C>T p.P2094L | Missense Mutation (SNP) | VAF 401/1051 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52114696; called by muse, mutect2, varscan2
- CTCF | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50464182; called by muse, mutect2, varscan2
- CUBN | c.6277G>A p.G2093S | Missense Mutation (SNP) | VAF 53/234 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759351780, COSV100913631, COSV64709447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUBN | c.5131G>A p.A1711T | Missense Mutation (SNP) | VAF 165/538 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.337); catalogued as rs768182223, COSV64725333; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL5 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63230139; called by muse, mutect2
- CUX2 | c.357del p.S120Afs*39 | Frame Shift Del (DEL) | VAF 30/126 reads (24%) | catalogued as rs762562717, COSV55632180; called by mutect2, pindel, varscan2
- DAGLA | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.296); catalogued as COSV57193778, COSV57197770; called by muse, mutect2, varscan2
- DCHS2 | c.1457del p.P486Qfs*34 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs767409155; called by pindel, varscan2
- DEFB129 | c.174A>C p.K58N | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV55731225; called by muse, mutect2, varscan2
- DELE1 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs200841874; called by muse, mutect2, varscan2
- DGKH | c.2941G>A p.A981T | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs778461926, COSV54936970, COSV54942411; called by muse, mutect2, varscan2
- DMD | c.2818C>T p.P940S | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1417425570; called by muse, mutect2, varscan2
- DMRTA1 | c.994A>T p.I332F | Missense Mutation (SNP) | VAF 14/265 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100364701; called by muse, mutect2
- DNAH1 | c.8492G>A p.R2831H | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as rs777520631, COSV70236892; called by muse, mutect2, varscan2
- DNAH9 | c.3918G>T p.W1306C | Missense Mutation (SNP) | VAF 77/230 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99305543; called by muse, mutect2, varscan2
- DNAJC2 | c.1173-7del | Splice Region (DEL) | VAF 30/94 reads (32%) | catalogued as rs538091160; called by mutect2, varscan2
- DNHD1 | c.4652G>A p.R1551Q | Missense Mutation (SNP) | VAF 91/306 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as rs758112886; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs782552436; called by mutect2, varscan2
- DOCK7 | c.1419del p.F473Lfs*8 | Frame Shift Del (DEL) | VAF 19/103 reads (18%) | catalogued as rs1557822062, COSV51995102; called by mutect2, pindel, varscan2
- DYSF | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 144/436 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.047); catalogued as rs1042263359, COSV50272050; called by muse, mutect2, varscan2
- DYSF | c.2380G>A p.V794I | Missense Mutation (SNP) | VAF 104/340 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs371609233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- E2F1 | c.1303del p.L435Wfs*58 | Frame Shift Del (DEL) | VAF 23/100 reads (23%) | catalogued as rs1409099723, COSV55776265; called by mutect2, pindel, varscan2
- ECEL1 | c.1057dup p.H353Pfs*59 | Frame Shift Ins (INS) | VAF 37/281 reads (13%) | catalogued as rs762901217; called by mutect2, pindel, varscan2
- ECSIT | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 151/478 reads (32%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs752446723; called by muse, mutect2, varscan2
- EGFR | c.2495G>A p.R832H | Missense Mutation (SNP) | VAF 142/393 reads (36%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.815); catalogued as rs772091823, COSV51783638, COSV51785438; called by muse, mutect2, varscan2
- EI24 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs555329927; called by muse, mutect2, varscan2
- ELP4 | c.747del p.K249Nfs*6 (on ENST00000350638; = p.K248Nfs*6 on NM_019040.5) | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | catalogued as COSV63351931; called by mutect2, pindel, varscan2
- EMILIN2 | c.508del p.V170* | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs1281163907; called by mutect2, pindel, varscan2
- EPC1 | c.1786G>T p.A596S | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.205); catalogued as rs1359914427; called by muse, mutect2, varscan2
- ERBB3 | c.1064C>A p.T355N | Missense Mutation (SNP) | VAF 128/370 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57247611; called by muse, mutect2, varscan2
- ESRRG | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs1265254562; called by muse, mutect2, varscan2
- ESYT2 | c.1972G>A p.E658K (on ENST00000613624; = p.E582K on NM_020728.3) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as rs547900513, COSV51758182; called by muse, mutect2, varscan2
- FAM187A | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1453848416; called by muse, varscan2
- FAM47A | c.295A>G p.K99E | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1239343277; called by muse, mutect2, varscan2
- FAM83E | c.1411del p.R471Gfs*70 | Frame Shift Del (DEL) | VAF 43/143 reads (30%) | catalogued as rs754029394, COSV52374478; called by mutect2, pindel, varscan2
- FASTKD5 | c.2000del p.G667Afs*6 | Frame Shift Del (DEL) | VAF 47/457 reads (10%) | catalogued as rs1233549844; called by mutect2, pindel, varscan2
- FAT3 | c.11728C>T p.R3910C | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.97); catalogued as rs1244798582; called by muse, mutect2
- FBN1 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as rs368089138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN1 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 96/269 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781113082, COSV57313288; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXW9 | c.988G>A p.V330M (on ENST00000587955; = p.V310M on NM_032301.3) | Missense Mutation (SNP) | VAF 237/758 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs766271599, COSV66710307; called by muse, mutect2, varscan2
- FCGBP | c.447del p.G150Afs*25 | Frame Shift Del (DEL) | VAF 69/178 reads (39%) | catalogued as rs765680504; called by mutect2, varscan2
- FES | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1450331775; called by muse, mutect2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 46/136 reads (34%) | catalogued as rs144178676; called by mutect2, varscan2
- FHDC1 | c.3011G>A p.R1004H | Missense Mutation (SNP) | VAF 91/272 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs759202401, COSV99471172; called by muse, mutect2, varscan2
- FITM2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 146/419 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as rs1274838151, COSV67679427; called by muse, mutect2, varscan2
- FKBP10 | c.1034dup p.H346Afs*27 | Frame Shift Ins (INS) | VAF 70/271 reads (26%) | catalogued as rs1555616685; called by mutect2, pindel, varscan2
- FLG | c.9793G>A p.G3265R | Missense Mutation (SNP) | VAF 181/983 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as rs144217264; called by muse, varscan2
- FLNA | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 16/451 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as rs200673062, COSV61038114; ClinVar: likely benign; called by muse, mutect2
- FLT4 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 19/443 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56098414; called by muse, mutect2
- FMO2 | c.575T>C p.M192T | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs368987902; called by muse, mutect2, varscan2
- FOCAD | c.4131del p.G1378Vfs*12 | Frame Shift Del (DEL) | VAF 36/115 reads (31%) | catalogued as rs887086186, COSV58105885; called by mutect2, pindel, varscan2
- FOXK2 | c.720G>T p.Q240H | Missense Mutation (SNP) | VAF 99/337 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100081771; called by mutect2, varscan2
- FOXRED2 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs147194835; called by muse, mutect2, varscan2
- FRAS1 | c.10960C>T p.R3654C | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755221317, COSV53603173; called by muse, mutect2, varscan2
- FURIN | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs1274395518, COSV99184749; called by muse, mutect2
- FXR1 | c.1319G>A p.R440K | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV59761062; called by muse, mutect2
- GDPD2 | c.209+1G>A p.X70_splice | Splice Site (SNP) | VAF 97/229 reads (42%) | catalogued as COSV100978731; called by muse, mutect2, varscan2
- GEN1 | c.920G>T p.R307M | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58056014; called by muse, mutect2, varscan2
- GJA10 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 92/302 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as COSV101005275; called by muse, mutect2, varscan2
- GK2 | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1237457253; called by muse, mutect2
- GLI2 | c.1447G>A p.E483K (on ENST00000361492 / NM_001374353.1; = p.E500K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs750260084; called by muse, varscan2
- GLRA1 | c.801G>T p.W267C | Missense Mutation (SNP) | VAF 152/492 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM045377; called by muse, mutect2, varscan2
- GLT1D1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs760181717, COSV55890033; called by muse, mutect2, varscan2
- GNB1 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.764); catalogued as COSV66101816; called by muse, mutect2, varscan2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 34/118 reads (29%) | catalogued as rs763679060; called by mutect2, varscan2
- GOLGA6A | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 208/1127 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs553319976; called by muse, mutect2, varscan2
- GPAT4 | c.822G>A p.M274I | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs765075072; called by muse, mutect2, varscan2
- GPC6 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs763966830, COSV65498863; called by muse, mutect2, varscan2
- GPR156 | c.2090G>A p.R697H | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs200929093; called by muse, mutect2, varscan2
- GREB1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 35/149 reads (23%) | catalogued as rs549613913; called by muse, mutect2, varscan2
- GRINA | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 108/320 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100507439; called by muse, mutect2, varscan2
- GRM6 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 25/436 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV51449672, COSV99179585; called by muse, mutect2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | catalogued as COSV58842099; called by mutect2, pindel, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 21/46 reads (46%) | catalogued as rs754199513; called by mutect2, varscan2
- GSG1 | c.605C>T p.A202V (on ENST00000651961 / NM_001080555.4; = p.R207= on NM_031289.5) | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs1247715514; called by muse, mutect2, varscan2
- GTF3C5 | c.872T>C p.M291T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1394891686; called by muse, mutect2, varscan2
- H1-7 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 31/520 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs776021579; called by muse, mutect2
- HAX1 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 139/910 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.864); catalogued as rs1379181768; called by muse, mutect2, varscan2
- HEBP1 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.75); catalogued as rs201807495; called by muse, mutect2
- HECA | c.716T>C p.L239P | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.804); catalogued as rs1471709648; called by muse, mutect2, varscan2
- HELZ2 | c.6616del p.R2206Vfs*29 (on ENST00000467148 / NM_001037335.2; = p.R1637Vfs*29 on NM_033405.3) | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | catalogued as rs745497383, COSV101427649; called by mutect2, varscan2
- HELZ2 | c.3562C>T p.R1188W (on ENST00000467148 / NM_001037335.2; = p.R619W on NM_033405.3) | Missense Mutation (SNP) | VAF 35/478 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs1478674415, COSV64409525; called by muse, mutect2
- HERC2 | c.6077C>T p.T2026M | Missense Mutation (SNP) | VAF 18/445 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs748164478; called by muse, mutect2
- HIRA | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as rs774636516, COSV54280338; called by muse, mutect2, varscan2
- HIRIP3 | c.13_15del p.K5del | In Frame Del (DEL) | VAF 87/330 reads (26%) | catalogued as rs768150257; called by mutect2, pindel, varscan2
- HNRNPCL1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as rs765183155, COSV58610621; called by muse, mutect2, varscan2
- HSF5 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 11/278 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV60416270; called by muse, mutect2
- HSPG2 | c.7198G>A p.A2400T | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs148674648; called by muse, mutect2, varscan2
- HTR1A | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 26/568 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as COSV60501172; called by muse, mutect2
- HYDIN | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372720976, COSV55481350; called by muse, mutect2, varscan2
- ICAM4 | c.38del p.L13Wfs*40 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as rs753968171; called by mutect2, varscan2
- ICE1 | c.3134C>T p.A1045V | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99665662; called by muse, mutect2
- IFFO2 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs868342990, COSV69085562; called by muse, mutect2
- IFI44L | c.509G>T p.R170M | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV60729172; called by muse, mutect2, varscan2
- IGF2R | c.4507G>A p.A1503T | Missense Mutation (SNP) | VAF 92/276 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as rs755636304; called by muse, mutect2, varscan2
- IL17RA | c.1489G>A p.G497S | Missense Mutation (SNP) | VAF 214/620 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs745681628, COSV60053066; called by muse, mutect2, varscan2
- IL2RG | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 93/317 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs774953764, COSV52149447; called by muse, mutect2, varscan2
- IL4I1 | c.917del p.P306Rfs*5 | Frame Shift Del (DEL) | VAF 49/202 reads (24%) | catalogued as COSV55578869, COSV99680473; called by mutect2, pindel, varscan2
- ILK | c.1169T>C p.V390A | Missense Mutation (SNP) | VAF 15/396 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs989611359; called by muse, mutect2
- INPP4B | c.2452dup p.R818Kfs*26 | Frame Shift Ins (INS) | VAF 66/196 reads (34%) | catalogued as rs772784869; called by mutect2, varscan2
- INPP5D | c.1654C>T p.R552* (on ENST00000445964 / NM_001017915.3; = p.R551* on NM_005541.5) | Nonsense Mutation (SNP) | VAF 7/128 reads (5%) | catalogued as COSV64038649; called by muse, mutect2
- INPP5F | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs753033639, COSV62823204; called by muse, mutect2, varscan2
- INTS1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.097); catalogued as rs545764403, COSV104431329; called by muse, mutect2, varscan2
- IPO13 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); catalogued as rs562766054, COSV64894109; called by muse, mutect2, varscan2
- IRAK2 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 119/272 reads (44%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.656); catalogued as rs1486419061, COSV99843932; called by muse, mutect2, varscan2
- ITGAL | c.1825G>A p.V609M | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as rs750373265, COSV63322312; called by muse, mutect2, varscan2
- JRK | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs587604633; called by muse, mutect2, varscan2
- KALRN | c.4480C>T p.R1494W | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53752833; called by muse, mutect2, varscan2
- KCNA5 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 157/471 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs1555100213, COSV99363588; called by muse, mutect2, varscan2
- KCNB2 | c.2416G>T p.E806* | Nonsense Mutation (SNP) | VAF 67/207 reads (32%) | catalogued as COSV73052121; called by muse, mutect2, varscan2
- KCND3 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs1271251092, COSV56183610, COSV56190019; called by muse, mutect2, varscan2
- KCNN3 | c.543C>A p.S181R | Missense Mutation (SNP) | VAF 62/415 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as rs1169663679, COSV55221316, COSV55221915; called by muse, mutect2, varscan2
- KCNV1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 125/453 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV52085240; called by muse, mutect2, varscan2
- KCTD13 | c.544T>C p.Y182H | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100441947; called by muse, mutect2, varscan2
- KDM2A | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 154/489 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV58189016; called by muse, mutect2, varscan2
- KIAA0753 | c.1499A>G p.N500S | Missense Mutation (SNP) | VAF 96/286 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1448399150; called by muse, mutect2, varscan2
- KIAA0930 | c.655C>T p.R219W (on ENST00000336156 / NM_001009880.2; = p.R224W on NM_015264.2) | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs778901989; called by muse, varscan2
- KIAA1217 | c.2927G>A p.R976K | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs145827639; called by muse, mutect2, varscan2
- KIR2DL4 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1464936898; called by muse, mutect2
- KIRREL1 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 85/567 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as rs368818824; called by muse, mutect2, varscan2
- KLF7 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.191); catalogued as rs536720710, COSV100519156; called by muse, mutect2, varscan2
- KLHL10 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.742); catalogued as rs566424838, COSV99509635; called by muse, mutect2
- KLHL25 | c.1040del p.G347Afs*29 | Frame Shift Del (DEL) | VAF 60/158 reads (38%) | catalogued as rs760548052, COSV100563595; called by mutect2, varscan2
- KLHL32 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 46/164 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV100987428; called by muse, mutect2, varscan2
- KNDC1 | c.3757G>A p.G1253S | Missense Mutation (SNP) | VAF 167/386 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749849751; called by muse, mutect2, varscan2
- KPNA3 | c.755A>C p.Y252S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV55503333; called by muse, mutect2, varscan2
- LAMB3 | c.1687del p.R563Afs*63 | Frame Shift Del (DEL) | VAF 77/490 reads (16%) | catalogued as COSV100620578; called by mutect2, pindel, varscan2
- LAMC1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51132524, COSV99278997; called by muse, mutect2, varscan2
- LANCL3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs782195768; called by muse, mutect2
- LARP1B | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as rs778089602, COSV52794328; called by muse, mutect2
- LEO1 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs765536535, COSV55176971; called by muse, mutect2, varscan2
- LGALS9 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 125/390 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780439566, COSV56347947; called by muse, mutect2, varscan2
- LPCAT1 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560973042; called by muse, mutect2
- LRATD2 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 17/458 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs1484583249; called by muse, mutect2
- LRPAP1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 34/500 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1175921366, COSV56347360; called by muse, mutect2
- LRRC17 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs764007775; called by muse, mutect2, varscan2
- LRRC37A3 | c.4040C>T p.A1347V | Missense Mutation (SNP) | VAF 148/446 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs373038175; called by muse, mutect2, varscan2
- LRRC66 | c.1708C>A p.R570S | Missense Mutation (SNP) | VAF 82/282 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs758645688; called by muse, mutect2, varscan2
- LRRCC1 | c.533G>A p.C178Y | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490055949; called by muse, mutect2, varscan2
- MACROH2A2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs375816544; called by muse, mutect2, varscan2
- MAP1B | c.2371G>A p.A791T | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV57107278; called by muse, mutect2
- MAP3K10 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV53422278; called by muse, mutect2
- MAPK4 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 120/347 reads (35%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.908); catalogued as rs764672737; called by muse, mutect2, varscan2
- MARK4 | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 96/283 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.34); catalogued as rs200675001, COSV99489093; called by muse, mutect2, varscan2
- MAST4 | c.1048C>T p.R350C (on ENST00000403625 / NM_001164664.2; = p.R161C on NM_015183.3) | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200510303; called by muse, mutect2, varscan2
- MCM3AP | c.2998G>A p.V1000I | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs779913783; called by muse, mutect2
- MCM8 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1282796391; called by muse, mutect2, varscan2
- MED9 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 205/642 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200780533, COSV51957209; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 68/240 reads (28%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MKI67 | c.7949C>T p.A2650V | Missense Mutation (SNP) | VAF 91/295 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as rs750187841, COSV64076683; called by muse, mutect2, varscan2
- MKRN3 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 94/226 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.347); catalogued as rs908492731, COSV58812071; called by muse, mutect2, varscan2
- MLXIP | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs756034052; called by muse, mutect2, varscan2
- MMP17 | c.1717del p.A573Pfs*29 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs1299468962, COSV62178756; called by mutect2, pindel, varscan2
- MORC4 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1366297708, COSV55242913; called by muse, mutect2
- MPEG1 | c.1679del p.G560Afs*43 | Frame Shift Del (DEL) | VAF 78/321 reads (24%) | catalogued as rs777449563; called by mutect2, pindel, varscan2
- MPP3 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as rs944159805, COSV68198848; called by muse, mutect2, varscan2
- MRGPRD | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs900414568, COSV58422659; called by muse, mutect2, varscan2
- MRGPRX1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as rs752611901, COSV100245786, COSV57107242, COSV57107590; called by muse, mutect2, varscan2
- MRPS9 | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV99305779; called by muse, mutect2, varscan2
- MST1 | c.1571C>T p.S524F | Missense Mutation (SNP) | VAF 25/586 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1346747192; called by muse, mutect2
- MTCH2 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765893027; called by muse, mutect2, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs759847587; called by mutect2, varscan2
- MTSS2 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1382544571; called by muse, mutect2
- MYBPH | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs752666685; called by muse, mutect2, varscan2
- MYCBP2 | c.7648C>T p.P2550S (on ENST00000357337; = p.P2588S on NM_015057.5) | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as COSV62025051; called by muse, mutect2
- MYCT1 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 123/330 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.26); catalogued as rs149668806; called by muse, mutect2, varscan2
- MYH11 | c.4511G>A p.R1504Q | Missense Mutation (SNP) | VAF 229/765 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs769614526; called by muse, mutect2, varscan2
- MYH8 | c.1266+1G>A p.X422_splice | Splice Site (SNP) | VAF 20/599 reads (3%) | catalogued as COSV67960308; called by muse, mutect2
- MYOM2 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs570741458; called by muse, mutect2, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 54/142 reads (38%) | catalogued as rs763929397; called by mutect2, varscan2
- NBPF3 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.403); catalogued as rs763934041, COSV100558998; called by muse, varscan2
- NCAPH | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs756191587, COSV53635271; called by muse, mutect2, varscan2
- NCKAP1 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs184228927; called by muse, mutect2, varscan2
- NCOA2 | c.1995_1998del p.N665Kfs*41 | Frame Shift Del (DEL) | VAF 50/152 reads (33%) | catalogued as rs1307457412; called by pindel, varscan2
- NCSTN | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 171/1094 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as rs769698945, COSV54186509; called by muse, mutect2, varscan2
- NDST2 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 108/336 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs773724006, COSV100014321; called by muse, mutect2, varscan2
- NDUFA10 | c.604del p.H202Tfs*3 | Frame Shift Del (DEL) | VAF 98/324 reads (30%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, varscan2
- NEBL | c.2025_2026del p.R675Sfs*14 | Frame Shift Del (DEL) | VAF 105/436 reads (24%) | catalogued as rs763778231; called by pindel, varscan2
- NEFL | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 32/752 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV99647989; called by muse, mutect2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 27/157 reads (17%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NFASC | c.3050C>T p.T1017M | Missense Mutation (SNP) | VAF 88/520 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs756101258; called by muse, mutect2, varscan2
- NIBAN2 | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1419855882, COSV55938376; called by muse, mutect2
- NID1 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 132/767 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs777371659, COSV51617543; called by muse, mutect2, varscan2
- NKX1-2 | c.428del p.P143Rfs*52 | Frame Shift Del (DEL) | VAF 12/115 reads (10%) | catalogued as rs918341173; called by mutect2, pindel, varscan2
- NLRP5 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 10/295 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs1369723841; called by muse, mutect2
- NLRP8 | c.2532G>A p.L844= | Splice Region (SNP) | VAF 31/77 reads (40%) | catalogued as rs776833597; called by muse, mutect2, varscan2
- NOC4L | c.907del p.X303_splice | Splice Site (DEL) | VAF 24/78 reads (31%) | catalogued as rs765400964; called by mutect2, pindel, varscan2
- NOL8 | c.418-8del | Splice Region (DEL) | VAF 17/46 reads (37%) | catalogued as rs756440973; called by mutect2, varscan2
- NOTCH4 | c.5672dup p.G1892Rfs*24 | Frame Shift Ins (INS) | VAF 52/192 reads (27%) | catalogued as rs777647776; called by mutect2, varscan2
- NRXN2 | c.2242G>T p.A748S | Missense Mutation (SNP) | VAF 28/732 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.052); catalogued as COSV55454587, COSV55456653; called by muse, mutect2
- NRXN3 | c.665G>A p.R222H (on ENST00000557594 / NM_001272020.2; = p.R854H on NM_004796.6) | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs1216934692, COSV99816367; called by muse, mutect2, varscan2
- NUMA1 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 11/281 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs978255940, COSV61189896; called by muse, mutect2
- OBSCN | c.4102G>A p.A1368T | Missense Mutation (SNP) | VAF 114/633 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.53); catalogued as COSV52742356; called by muse, mutect2, varscan2
- OLFML2B | c.2162C>T p.T721M | Missense Mutation (SNP) | VAF 61/336 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs780240007, COSV54200065; called by muse, mutect2, varscan2
- OR12D3 | c.180del p.L61Wfs*14 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | catalogued as rs762417164; called by mutect2, pindel, varscan2
- OR1D5 | c.742G>T p.V248F | Missense Mutation (SNP) | VAF 76/218 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1296527279; called by muse, mutect2, varscan2
- OR2M2 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 124/852 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.117); catalogued as COSV100677147; called by muse, mutect2
- OSBPL3 | c.2120T>C p.V707A | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs765890499; called by muse, mutect2, varscan2
- OSMR | c.640T>C p.Y214H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1045054711; called by muse, mutect2
- OTOG | c.8404C>T p.R2802C | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.385); catalogued as rs952407320; called by muse, mutect2
- OTUD6B | c.783del p.K261Nfs*3 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | catalogued as rs762934606; called by mutect2, pindel
- P2RY8 | c.109A>G p.S37G | Missense Mutation (SNP) | VAF 28/530 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs1408368388; called by muse, mutect2
- PAPLN | c.2611del p.H871Tfs*93 (on ENST00000554301; = p.H844Tfs*93 on NM_173462.4) | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs1291107616; called by mutect2, pindel, varscan2
- PAPOLG | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs775120420, COSV99475137; called by muse, mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 23/68 reads (34%) | catalogued as rs753190856; called by mutect2, varscan2
- PCDHA6 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 119/410 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.036); catalogued as rs148379064, COSV65347147; called by muse, mutect2, varscan2
- PCDHGA1 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 40/686 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.035); catalogued as rs371049984; called by muse, mutect2
- PCDHGA3 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.038); catalogued as rs1259196746; called by muse, mutect2, varscan2
- PCDHGA6 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 22/507 reads (4%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); catalogued as rs1331529697; called by muse, mutect2
- PCDHGA8 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 154/439 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.041); catalogued as rs771645801, COSV53955769; called by muse, mutect2, varscan2
- PCLO | c.2467C>T p.R823* | Nonsense Mutation (SNP) | VAF 74/223 reads (33%) | catalogued as COSV61614801; called by muse, mutect2, varscan2
- PCSK5 | c.1939G>A p.G647R | Missense Mutation (SNP) | VAF 118/354 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406686253, COSV65084371; called by muse, varscan2
- PCYT1A | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1271650484; called by muse, mutect2, varscan2
- PDP1 | c.317T>A p.V106D | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV52604204; called by muse, mutect2, varscan2
- PDX1 | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs981314993; called by muse, mutect2, varscan2
- PER1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 111/424 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs372164120; called by muse, mutect2, varscan2
- PGF | c.608+1G>A p.X203_splice | Splice Site (SNP) | VAF 19/65 reads (29%) | catalogued as rs1311947184; called by muse, mutect2, varscan2
- PGGHG | c.1649A>G p.D550G | Missense Mutation (SNP) | VAF 84/263 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs764391787; called by muse, mutect2, varscan2
- PHACTR2 | c.13+2T>C p.X5_splice | Splice Site (SNP) | VAF 117/390 reads (30%) | catalogued as COSV59850684; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs1163689977; called by mutect2, pindel
- PHLPP2 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs936979462; called by muse, mutect2
- PI4KB | c.595G>A p.V199I (on ENST00000368873 / NM_001369623.1; = p.V211I on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs777415980; called by muse, mutect2, varscan2
- PIK3R1 | c.1109T>C p.L370P (on ENST00000521381 / NM_181523.3; = p.L100P on NM_181504.4) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57140476; called by muse, mutect2, varscan2
- PITPNB | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV58060951; called by muse, mutect2, varscan2
- PITPNM3 | c.2423_2425del p.F808del | In Frame Del (DEL) | VAF 110/411 reads (27%) | catalogued as rs754410582; called by pindel, varscan2
- PLCB3 | c.2948G>A p.R983Q | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as rs1419520120; called by muse, mutect2
- PLEKHH3 | c.574del p.V192Wfs*6 | Frame Shift Del (DEL) | VAF 38/150 reads (25%) | catalogued as rs778393033; called by mutect2, pindel, varscan2
- PLXNA3 | c.5134C>T p.R1712C | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1557209140; called by muse, mutect2
- PLXNA4 | c.3261G>T p.E1087D | Missense Mutation (SNP) | VAF 76/240 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV58155758; called by muse, mutect2, varscan2
- PMS2 | c.1288A>G p.T430A | Missense Mutation (SNP) | VAF 112/372 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs587781382; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- POFUT2 | c.158del p.P53Rfs*18 | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | catalogued as COSV99044753; called by mutect2, pindel
- POGK | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 114/556 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.953); catalogued as rs769898418, COSV63311426; called by muse, mutect2, varscan2
- POLD3 | c.1147C>T p.R383* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as rs761391963, COSV99738021; called by muse, mutect2, varscan2
- POLG2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 166/500 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs112240735; called by mutect2, varscan2
- POLR1D | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566140775; called by muse, mutect2
- POTEI | c.2182del p.R728Gfs*16 | Frame Shift Del (DEL) | VAF 38/312 reads (12%) | catalogued as rs775721804; called by mutect2, pindel, varscan2
- PPP1R10 | c.1753C>T p.L585F | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1249046708; called by muse, mutect2
- PRKN | c.1060G>T p.G354W | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV58210320, COSV58244936; called by muse, mutect2, varscan2
- PROKR1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs371409546, COSV58136615; called by muse, mutect2, varscan2
- PRPF6 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV99412352; called by muse, mutect2
- PRRC2B | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 93/261 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as rs763942220; called by muse, mutect2, varscan2
- PRRC2C | c.4728_4730del p.R1577del (on ENST00000367742; = p.R1575del on NM_015172.4) | In Frame Del (DEL) | VAF 14/86 reads (16%) | catalogued as rs767056990; called by mutect2, pindel
- PRRG3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64851543; called by muse, mutect2, varscan2
- PRRX1 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 94/542 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs756620309, COSV53415959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRSS22 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs760100029, COSV99362031; called by muse, mutect2, varscan2
- PSMD2 | c.2039G>T p.R680I | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100031608; called by muse, mutect2, varscan2
- PTPRO | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.039); catalogued as COSV55504354, COSV55519530; called by muse, mutect2
- PUF60 | c.1652G>A p.R551H (on ENST00000526683 / NM_001362896.2; = p.R534H on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.915); catalogued as rs1458777514; called by muse, mutect2
- PWWP2B | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs1344450844; called by muse, mutect2
- R3HCC1 | c.1268C>T p.T423I (on ENST00000411463; = p.T383I on NM_001136108.3) | Missense Mutation (SNP) | VAF 130/424 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.138); catalogued as rs944392405; called by muse, varscan2
- RAB3GAP1 | c.153T>C p.G51= | Splice Region (SNP) | VAF 16/67 reads (24%) | catalogued as rs1388728601, COSV51480060; called by muse, mutect2, varscan2
- RASGRF1 | c.1016A>G p.N339S | Missense Mutation (SNP) | VAF 15/326 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69180789; called by muse, mutect2
- RBBP6 | c.1606C>T p.R536* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV60505454; called by muse, mutect2, varscan2
- RFPL1 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 46/466 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.069); catalogued as rs750966646; called by muse, mutect2, varscan2
- RFX1 | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 27/409 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1407974879; called by muse, mutect2
- RFX1 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs374974524, COSV54334173; called by muse, mutect2, varscan2
- RGPD4 | c.4803del p.K1601Nfs*69 | Frame Shift Del (DEL) | VAF 60/297 reads (20%) | catalogued as rs1558816973; called by mutect2, pindel, varscan2
- RGS12 | c.3870dup p.G1291Rfs*45 | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | catalogued as rs751982308; called by mutect2, varscan2
- RNF44 | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as rs952335772; called by muse, mutect2, varscan2
- ROBO3 | c.571del p.R191Afs*31 | Frame Shift Del (DEL) | VAF 70/239 reads (29%) | catalogued as rs756837590; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- RP1 | c.458del p.P153Hfs*4 | Frame Shift Del (DEL) | VAF 76/253 reads (30%) | catalogued as rs781249059; called by mutect2, pindel, varscan2
- RPL18A | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.411); catalogued as rs1157468335; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 55/174 reads (32%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RTEL1 | c.2268G>A p.M756I | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.269); catalogued as rs938432778; called by muse, mutect2
- RTF2 | c.17del p.G6Efs*10 | Frame Shift Del (DEL) | VAF 27/126 reads (21%) | catalogued as COSV50128608; called by mutect2, pindel, varscan2
- S1PR3 | c.340A>G p.R114G | Missense Mutation (SNP) | VAF 87/289 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104419839; called by muse, mutect2, varscan2
- SAMD9L | c.4224del p.K1408Nfs*10 | Frame Shift Del (DEL) | VAF 26/101 reads (26%) | catalogued as rs759143613, COSV59085428; called by mutect2, pindel, varscan2
- SCG3 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs150761131; called by muse, mutect2, varscan2
- SCN10A | c.2597G>A p.C866Y | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71861825; called by muse, mutect2, varscan2
- SCRIB | c.3287del p.P1096Rfs*44 | Frame Shift Del (DEL) | VAF 69/571 reads (12%) | catalogued as COSV57588543; called by mutect2, pindel, varscan2
- SDK2 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 108/351 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754190867, COSV101168232; called by muse, mutect2, varscan2
- SEC16B | c.1775+6C>T | Splice Region (SNP) | VAF 111/614 reads (18%) | catalogued as rs763489398, COSV100381497; called by muse, mutect2, varscan2
- SETBP1 | c.2606G>T p.S869I | Missense Mutation (SNP) | VAF 114/321 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56327968; called by muse, mutect2, varscan2
- SF3A2 | c.198+6G>A | Splice Region (SNP) | VAF 18/243 reads (7%) | catalogued as rs1404507467; called by muse, mutect2
- SF3A2 | c.869del p.P290Rfs*156 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as rs1404234638; called by mutect2, pindel, varscan2
- SFT2D3 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 118/344 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV59252261; called by muse, mutect2, varscan2
- SH2B1 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 79/232 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs766274908, COSV59463379; called by muse, mutect2, varscan2
- SHANK2 | c.5048G>A p.G1683D | Missense Mutation (SNP) | VAF 107/346 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1555149277; called by muse, mutect2, varscan2
- SHISA6 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 33/676 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV58647611; called by muse, mutect2
- SIGLEC7 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58318220; called by muse, mutect2
- SIRT1 | c.709del p.R237Efs*11 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs1564883215; called by mutect2, pindel, varscan2
- SIX6 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs753099890, COSV100576544; called by muse, mutect2
- SLC12A6 | c.421G>A p.D141N (on ENST00000354181 / NM_001365088.1; = p.D90N on NM_005135.2) | Missense Mutation (SNP) | VAF 85/279 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as COSV51628603; called by muse, mutect2, varscan2
- SLC35D3 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 91/273 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); catalogued as COSV59378453; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC39A9 | c.293G>A p.S98N | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.084); catalogued as COSV50362488; called by muse, mutect2
- SLC45A4 | c.874G>A p.E292K (on ENST00000517878 / NM_001286646.2; = p.E241K on NM_001080431.2) | Missense Mutation (SNP) | VAF 83/289 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs765022689, COSV99198395; called by muse, mutect2, varscan2
- SLC46A1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs1555590784; called by muse, mutect2
- SLC7A13 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as rs1325071738, COSV52533853, COSV52537797; called by muse, mutect2, varscan2
- SLC9A5 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs754013008, COSV100237133; called by muse, mutect2, varscan2
- SLTM | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.92); PolyPhen benign (0.031); catalogued as COSV65848433; called by muse, mutect2
- SLX4 | c.2246G>A p.R749H | Missense Mutation (SNP) | VAF 138/413 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs140109914, COSV53564548; called by muse, mutect2, varscan2
- SMC4 | c.2972G>A p.R991H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs755432637, COSV59087396; called by mutect2, varscan2
- SMG7 | c.2545del p.M849* | Frame Shift Del (DEL) | VAF 57/340 reads (17%) | catalogued as rs749889899; called by mutect2, varscan2
- SNIP1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as rs57392277, COSV56167388; called by muse, mutect2, varscan2
- SOCS5 | c.1189G>T p.G397W | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100124944; called by muse, mutect2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 34/80 reads (43%) | catalogued as rs1278336874; called by mutect2, pindel, varscan2
- SOX9 | c.600dup p.N201Qfs*51 | Frame Shift Ins (INS) | VAF 80/319 reads (25%) | catalogued as COSV99818855; called by mutect2, pindel, varscan2
- SPHK2 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766472809; called by muse, mutect2, varscan2
- SPIRE1 | c.2039A>G p.D680G (on ENST00000409402 / NM_001128626.2; = p.D666G on NM_020148.3) | Missense Mutation (SNP) | VAF 87/222 reads (39%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.521); catalogued as COSV100563840; called by muse, mutect2, varscan2
- SPNS1 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 131/300 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201586251, COSV100209158, COSV57957107; called by mutect2, varscan2
- SPTA1 | c.5273T>C p.L1758P | Missense Mutation (SNP) | VAF 125/780 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320336457; called by muse, mutect2, varscan2
- SRP72 | c.1502+1G>A p.X501_splice | Splice Site (SNP) | VAF 17/76 reads (22%) | catalogued as rs750937171, COSV61378720; called by muse, mutect2, varscan2
- SSH1 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764564671; called by muse, mutect2, varscan2
- ST7 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 52/148 reads (35%) | catalogued as COSV99622669; called by muse, mutect2, varscan2
- STAT4 | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.236); catalogued as rs771889653, COSV61829721; called by muse, mutect2, varscan2
- STRADA | c.1197del p.I400Sfs*19 (on ENST00000336174 / NM_001363786.1; = p.I363Sfs*19 on NM_001003786.3) | Frame Shift Del (DEL) | VAF 41/150 reads (27%) | catalogued as rs1338109646; called by mutect2, pindel, varscan2
- SV2C | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753140281, COSV100455618; called by muse, mutect2, varscan2
- SYT12 | c.722G>A p.G241D | Missense Mutation (SNP) | VAF 197/599 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.414); catalogued as rs371381298; called by muse, mutect2, varscan2
- TAF1L | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 86/237 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1192501986, COSV54262894; called by muse, mutect2, varscan2
- TAGLN | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as rs11547376; called by muse, mutect2, varscan2
- TAOK1 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55588882; called by muse, mutect2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TCFL5 | c.1391G>A p.S464N | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.395); catalogued as COSV53898178; called by muse, mutect2, varscan2
- TECR | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 92/317 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as rs763449006, COSV53108136; called by muse, mutect2, varscan2
- TGFBI | c.1502del p.P501Qfs*9 | Frame Shift Del (DEL) | VAF 47/164 reads (29%) | catalogued as rs771515402; called by mutect2, pindel, varscan2
- TGIF2LX | c.599C>A p.P200Q | Missense Mutation (SNP) | VAF 154/562 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV99383280; called by muse, mutect2
- THSD7A | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282350197, COSV70275543; called by muse, mutect2
- TIFAB | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371948648; called by muse, mutect2
- TMCC1 | c.1504C>T p.R502* (on ENST00000393238 / NM_001349268.2; = p.R178* on NM_015008.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as rs1233409585, COSV61439948; called by muse, mutect2, varscan2
- TMEM100 | c.296del p.L99Yfs*2 | Frame Shift Del (DEL) | VAF 47/192 reads (24%) | catalogued as rs894486999; called by mutect2, pindel, varscan2
- TMEM121 | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 90/328 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.204); catalogued as rs782593364; called by mutect2, varscan2
- TMEM131L | c.523T>A p.S175T | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53645227; called by muse, mutect2, varscan2
- TNPO2 | c.2501dup p.V835Rfs*21 (on ENST00000425528 / NM_001382240.1; = p.V825Rfs*21 on NM_013433.5 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 60/250 reads (24%) | catalogued as rs776213759; called by mutect2, pindel, varscan2
- TNRC18 | c.8843C>T p.A2948V | Missense Mutation (SNP) | VAF 107/337 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746930389; called by muse, mutect2, varscan2
- TNRC18 | c.6038C>T p.A2013V | Missense Mutation (SNP) | VAF 138/376 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1472586877; called by muse, mutect2, varscan2
- TOGARAM2 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.273); catalogued as rs1325114627; called by muse, mutect2, varscan2
- TOR4A | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs888114734; called by muse, mutect2, varscan2
- TP73 | c.1175A>G p.Q392R | Missense Mutation (SNP) | VAF 71/256 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs761635975; called by muse, mutect2, varscan2
- TRAF2 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV56042525; called by muse, mutect2, varscan2
- TRAP1 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 91/315 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as rs749341264; called by muse, mutect2, varscan2
- TRIM64C | c.1263del p.F421Lfs*21 | Frame Shift Del (DEL) | VAF 82/284 reads (29%) | catalogued as rs745725792; called by mutect2, varscan2
- TRIM68 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 28/640 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs1340653253; called by muse, mutect2
- TRIO | c.2978C>T p.A993V | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV60077631; called by muse, mutect2, varscan2
- TRIO | c.5066C>T p.P1689L | Missense Mutation (SNP) | VAF 122/404 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs759701866; called by muse, mutect2, varscan2
- TRPM2 | c.2977C>A p.P993T | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.312); catalogued as COSV55968448; called by muse, mutect2
- TTC38 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237808303; called by muse, mutect2
- UBA6 | c.395A>G p.Y132C | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs532958624; called by muse, mutect2, varscan2
- UBR4 | c.4022C>T p.A1341V | Missense Mutation (SNP) | VAF 14/450 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0.135); catalogued as rs1039327762; called by muse, mutect2
- UBR5 | c.5776C>T p.R1926W | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55298590; called by muse, mutect2, varscan2
- UBXN8 | c.401T>C p.L134P | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs928206087; called by muse, mutect2, varscan2
- UNC13A | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.482); catalogued as rs1451260824, COSV53193485; called by muse, mutect2, varscan2
- UNC93B1 | c.399dup p.G134Wfs*59 | Frame Shift Ins (INS) | VAF 28/111 reads (25%) | catalogued as rs1490111244; called by mutect2, pindel, varscan2
- USP13 | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 102/315 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1472599132, COSV55868594; called by muse, mutect2, varscan2
- UST | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs775187633, COSV66546046; called by muse, mutect2, varscan2
- UTF1 | c.479del p.P160Rfs*116 | Frame Shift Del (DEL) | VAF 72/255 reads (28%) | catalogued as rs1376107929; called by mutect2, pindel, varscan2
- VAX2 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs782586068; called by muse, mutect2, varscan2
- VSTM2L | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 19/239 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); catalogued as rs1488030828; called by muse, mutect2
- VSTM4 | c.322del p.A108Rfs*8 | Frame Shift Del (DEL) | VAF 87/271 reads (32%) | catalogued as COSV53677499; called by mutect2, varscan2
- WAS | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 91/264 reads (34%) | catalogued as CM951331, COSV64997641; called by muse, mutect2, varscan2
- WDFY4 | c.5105G>A p.R1702H | Missense Mutation (SNP) | VAF 10/277 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.374); catalogued as rs1006734794; called by muse, mutect2
- WDR59 | c.479del p.N160Mfs*28 | Frame Shift Del (DEL) | VAF 68/172 reads (40%) | catalogued as rs762980273; called by mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 50/142 reads (35%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- XIRP2 | c.1537dup p.D513Gfs*10 (on ENST00000628543; = p.D688Gfs*10 on NM_152381.6) | Frame Shift Ins (INS) | VAF 34/108 reads (31%) | catalogued as rs745648385; called by mutect2, varscan2
- YWHAG | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 108/309 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); catalogued as COSV56901032; called by muse, mutect2, varscan2
- YY1AP1 | c.293A>G p.Q98R (on ENST00000295566 / NM_139118.2; = p.Q21R on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/712 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1405576071; called by muse, varscan2
- ZC3H4 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 131/335 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as rs368291425; called by muse, mutect2, varscan2
- ZER1 | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 102/323 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.967); catalogued as rs11097; called by muse, mutect2, varscan2
- ZFAT | c.3433G>A p.A1145T | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); catalogued as rs377173690; called by muse, mutect2, varscan2
- ZFHX3 | c.3313C>T p.Q1105* | Nonsense Mutation (SNP) | VAF 150/380 reads (39%) | catalogued as COSV99212864; called by muse, mutect2, varscan2
- ZFHX4 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 43/148 reads (29%) | catalogued as rs768552335, COSV99266896; called by muse, mutect2, varscan2
- ZFHX4 | c.3797C>T p.T1266M | Missense Mutation (SNP) | VAF 87/339 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs763149017, COSV51467227; called by muse, mutect2, varscan2
- ZFP36L2 | c.88A>G p.M30V | Missense Mutation (SNP) | VAF 84/280 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.444); catalogued as rs745522686, COSV56698503; called by muse, mutect2, varscan2
- ZFP57 | c.529del p.C177Afs*25 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | catalogued as rs1272756745; called by mutect2, varscan2
- ZFYVE26 | c.2690G>A p.S897N | Missense Mutation (SNP) | VAF 23/635 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1371864759; called by muse, mutect2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 51/180 reads (28%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF124 | c.1015del p.T339Lfs*31 (on ENST00000543802 / NM_001297568.1; = p.T277Lfs*31 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | catalogued as COSV61506988; called by mutect2, pindel, varscan2
- ZNF180 | c.1600T>G p.S534A | Missense Mutation (SNP) | VAF 75/217 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs764815204; called by muse, mutect2, varscan2
- ZNF236 | c.1381del p.M461* | Frame Shift Del (DEL) | VAF 56/180 reads (31%) | catalogued as rs769237443, COSV53487827; called by mutect2, varscan2
- ZNF257 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.308); catalogued as rs1484419077; called by muse, mutect2, varscan2
- ZNF273 | c.1532A>G p.E511G | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as COSV100139386; called by muse, mutect2
- ZNF282 | c.1709G>A p.G570D | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100021692; called by muse, mutect2
- ZNF329 | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV63772738; called by muse, mutect2, varscan2
- ZNF48 | c.745del p.R249Dfs*43 | Frame Shift Del (DEL) | VAF 48/142 reads (34%) | catalogued as rs780189754; called by mutect2, varscan2
- ZNF521 | c.2810G>A p.R937Q | Missense Mutation (SNP) | VAF 112/340 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.98); catalogued as rs1389483666, COSV64123188; called by muse, mutect2, varscan2
- ZNF550 | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV57304359; called by muse, mutect2
- ZNF555 | c.1421A>G p.H474R | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1219091898; called by muse, mutect2, varscan2
- ZNF638 | c.4564A>G p.T1522A | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1323926859; called by muse, mutect2
- ZNF780B | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV55463582; called by muse, mutect2, varscan2
- ZNF93 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs373401112, COSV59375919; called by muse, mutect2, varscan2
- ZSCAN1 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.835); catalogued as rs764113791, COSV56601539, COSV56605865; called by muse, mutect2, varscan2
- ABCA10 | c.93del p.K31Nfs*18 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- ABCA5 | c.939dup p.A314Cfs*9 | Frame Shift Ins (INS) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- ABCC1 | c.1665C>G p.C555W | Missense Mutation (SNP) | VAF 167/420 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ABCC9 | c.4022del p.K1341Rfs*35 | Frame Shift Del (DEL) | VAF 39/158 reads (25%) | called by mutect2, pindel, varscan2
- ABCD4 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); called by muse, mutect2
- ABCG5 | c.1059G>T p.M353I | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2
- ABHD17C | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABTB2 | c.1117C>G p.P373A | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AC131160.1 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2
- ACHE | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 85/261 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ACO1 | c.2329G>A p.G777S | Missense Mutation (SNP) | VAF 99/319 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACOT1 | c.865T>C p.Y289H | Missense Mutation (SNP) | VAF 149/725 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ACP2 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 113/374 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACP3 | c.1130G>C p.S377T | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.023); called by muse, mutect2
- ACSL6 | c.1361T>G p.V454G (on ENST00000379240; = p.V479G on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ACTN1 | c.1590G>T p.E530D | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.238); called by muse, mutect2
- ADAM15 | c.1098del p.C367Vfs*22 | Frame Shift Del (DEL) | VAF 26/201 reads (13%) | called by mutect2, pindel, varscan2
- ADAM21 | c.1472A>G p.Q491R | Missense Mutation (SNP) | VAF 115/342 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- ADAMTS8 | c.2665dup p.L889Pfs*28 | Frame Shift Ins (INS) | VAF 29/84 reads (35%) | called by mutect2, pindel, varscan2
- ADCY3 | c.1732G>T p.D578Y | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.825); called by mutect2, varscan2
- ADGRB1 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, varscan2
- AFAP1L1 | c.1289A>C p.N430T | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2
- AGL | c.3772A>G p.T1258A | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AK7 | c.687del p.F229Lfs*21 | Frame Shift Del (DEL) | VAF 30/114 reads (26%) | called by mutect2, pindel, varscan2
- AK9 | c.1927T>G p.L643V | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- AKAP1 | c.512T>C p.F171S | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.342); called by muse, mutect2
- AKAP11 | c.898del p.S300Rfs*30 | Frame Shift Del (DEL) | VAF 29/124 reads (23%) | called by mutect2, pindel, varscan2
- ALAD | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 154/437 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALK | c.2434C>T p.H812Y | Missense Mutation (SNP) | VAF 113/353 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AMMECR1 | c.611del p.P204Qfs*2 | Frame Shift Del (DEL) | VAF 40/175 reads (23%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.6115G>A p.A2039T | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2
- ANKRD17 | c.1094A>G p.E365G | Missense Mutation (SNP) | VAF 8/197 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- ANKRD36 | c.1003G>T p.V335L | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ANOS1 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 20/448 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.094); called by muse, mutect2
- APC | c.1936A>G p.I646V | Missense Mutation (SNP) | VAF 86/261 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- APOA4 | c.994del p.H332Mfs*9 | Frame Shift Del (DEL) | VAF 173/588 reads (29%) | called by mutect2, pindel, varscan2
- APOOL | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ARAF | c.653T>C p.V218A | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ARHGEF10 | c.1645G>A p.A549T (on ENST00000398564; = p.A524T on NM_014629.4) | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2
- ARHGEF11 | c.2382A>C p.E794D | Missense Mutation (SNP) | VAF 15/337 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.48); called by muse, mutect2
- ARHGEF33 | c.2129_2130del p.K710Rfs*90 | Frame Shift Del (DEL) | VAF 36/138 reads (26%) | called by mutect2, pindel, varscan2
- ARHGEF4 | c.1289A>G p.Y430C | Missense Mutation (SNP) | VAF 102/295 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID1A | c.5693del p.P1898Hfs*25 | Frame Shift Del (DEL) | VAF 54/171 reads (32%) | called by mutect2, pindel, varscan2
- ARL3 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARRB2 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ART5 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- ASB2 | c.818A>C p.E273A | Missense Mutation (SNP) | VAF 17/372 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2
- ASPM | c.5113G>A p.A1705T | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ASPSCR1 | c.1561del p.A521Rfs*15 | Frame Shift Del (DEL) | VAF 53/161 reads (33%) | called by mutect2, pindel, varscan2
- ASXL3 | c.6034A>G p.K2012E | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATAD2B | c.1407G>A p.M469I | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- ATP11B | c.174T>A p.N58K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP2C2 | c.1443del p.E482Rfs*13 | Frame Shift Del (DEL) | VAF 8/83 reads (10%) | called by mutect2, pindel
- B3GNT5 | c.1047del p.F349Lfs*8 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- BAG1 | c.488A>G p.Q163R | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- BEST3 | c.634A>C p.T212P | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- BHMT2 | c.70A>T p.I24F | Missense Mutation (SNP) | VAF 98/294 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- BIRC5 | c.49C>A p.H17N | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BMS1 | c.2714A>G p.Y905C | Missense Mutation (SNP) | VAF 79/301 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- BTBD17 | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTN1A1 | c.1459A>G p.N487D | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTNL2 | c.1325del p.L442Wfs*? (on ENST00000374993; = p.L442Wfs*16 on NM_001304561.1) | Frame Shift Del (DEL) | VAF 39/114 reads (34%) | called by mutect2, pindel, varscan2
- C2CD3 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 105/356 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C5orf51 | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- C7orf31 | c.1639T>C p.S547P | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- CACNA1E | c.5774C>A p.P1925H | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CACNA1F | c.1471del p.A491Lfs*9 | Frame Shift Del (DEL) | VAF 57/211 reads (27%) | called by mutect2, pindel, varscan2
- CACNA1I | c.2542T>G p.F848V | Missense Mutation (SNP) | VAF 20/517 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2
- CACNA2D4 | c.1283del p.F428Sfs*15 | Frame Shift Del (DEL) | VAF 24/95 reads (25%) | called by mutect2, pindel, varscan2
- CAD | c.5635C>A p.P1879T | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPN5 | c.515T>G p.V172G (on ENST00000456580; = p.V132G on NM_004055.5) | Missense Mutation (SNP) | VAF 213/549 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CARMIL1 | c.2672T>C p.V891A | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARMIL3 | c.3278dup p.S1094* | Frame Shift Ins (INS) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- CASP9 | c.538C>A p.R180S | Missense Mutation (SNP) | VAF 96/331 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASZ1 | c.510G>T p.E170D | Missense Mutation (SNP) | VAF 103/337 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CAV3 | c.344A>G p.Q115R | Missense Mutation (SNP) | VAF 76/309 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.374); called by muse, varscan2
- CBX2 | c.1024G>T p.G342C | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- CCDC138 | c.1211dup p.L404Ffs*51 | Frame Shift Ins (INS) | VAF 26/94 reads (28%) | called by mutect2, pindel, varscan2
- CCDC18 | c.3297dup p.E1100Rfs*3 (on ENST00000343253 / NM_001306076.1; = p.E1101Rfs*3 on NM_206886.4) | Frame Shift Ins (INS) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
- CCDC191 | c.2256del p.G753Vfs*2 | Frame Shift Del (DEL) | VAF 34/132 reads (26%) | called by mutect2, pindel, varscan2
- CCDC28B | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.025); called by muse, mutect2
- CCDC81 | c.806C>T p.A269V (on ENST00000445632 / NM_001156474.2; = p.A179V on NM_021827.4) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CCDC88B | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- CCL26 | c.237del p.K79Nfs*10 | Frame Shift Del (DEL) | VAF 34/113 reads (30%) | called by mutect2, pindel, varscan2
- CCT3 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 79/498 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CD177 | c.491G>T p.R164M | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CDC37 | c.334A>G p.M112V | Missense Mutation (SNP) | VAF 77/249 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CDC40 | c.1367T>C p.I456T | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CDIPT | c.333-5C>T | Splice Region (SNP) | VAF 6/135 reads (4%) | called by muse, mutect2
- CDK10 | c.234C>T p.G78= (on ENST00000353379 / NM_052988.5; = p.G7= on NM_052987.4) | Splice Region (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- CDK13 | c.2733del p.K911Nfs*13 | Frame Shift Del (DEL) | VAF 30/117 reads (26%) | called by mutect2, pindel, varscan2
- CDKL4 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- CDKN2B | c.157-7_157-6del | Splice Region (DEL) | VAF 126/548 reads (23%) | called by pindel, varscan2
- CELF6 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 46/163 reads (28%) | called by mutect2, pindel, varscan2
- CENPC | c.37T>C p.Y13H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CENPF | c.5711T>C p.L1904P | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CENPJ | c.1997A>G p.E666G | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP72 | c.1377A>T p.E459D | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CEP89 | c.2247dup p.R750Qfs*26 | Frame Shift Ins (INS) | VAF 81/299 reads (27%) | called by mutect2, pindel, varscan2
- CEP95 | c.413T>C p.L138S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.232); called by muse, varscan2
- CFTR | c.2698A>G p.N900D | Missense Mutation (SNP) | VAF 75/202 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHD5 | c.3653C>A p.P1218H | Missense Mutation (SNP) | VAF 22/432 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2
- CHD7 | c.1909T>C p.S637P | Missense Mutation (SNP) | VAF 54/406 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- CHD7 | c.8003A>T p.D2668V | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- CHRM4 | c.471G>T p.W157C | Missense Mutation (SNP) | VAF 144/375 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CIC | c.2642C>T p.A881V | Missense Mutation (SNP) | VAF 128/332 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CISH | c.382A>G p.N128D (on ENST00000348721 / NM_145071.4; = p.N145D on NM_013324.6) | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CKB | c.631T>C p.W211R | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CMPK2 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- CNP | c.1238del p.G413Afs*19 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- CNTD1 | c.481_483del p.E161del | In Frame Del (DEL) | VAF 22/102 reads (22%) | called by pindel, varscan2
- CNTNAP1 | c.4030A>G p.T1344A | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP4 | c.109T>C p.S37P | Missense Mutation (SNP) | VAF 17/462 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- COL5A1 | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 38/740 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL6A5 | c.4559del p.N1520Tfs*94 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- COPB2 | c.1266del p.K422Nfs*23 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, varscan2
- COPS2 | c.633del p.N211Kfs*22 | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | called by mutect2, pindel, varscan2
- COPS3 | c.1218+2T>C p.X406_splice | Splice Site (SNP) | VAF 49/126 reads (39%) | called by muse, mutect2, varscan2
- COQ5 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 31/640 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.265); called by muse, mutect2
- CORO1A | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 115/310 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CORO2B | c.203T>C p.I68T | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- CRYBG1 | c.2965T>C p.C989R | Missense Mutation (SNP) | VAF 73/233 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CRYBG1 | c.4384G>C p.V1462L | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- CSMD3 | c.4247G>A p.G1416D (on ENST00000297405 / NM_001363185.1; = p.G1312D on NM_052900.3) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CTSS | c.202A>T p.M68L | Missense Mutation (SNP) | VAF 39/249 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CTTNBP2NL | c.1002dup p.L335Afs*19 | Frame Shift Ins (INS) | VAF 25/178 reads (14%) | called by mutect2, pindel, varscan2
- CUL9 | c.6345C>G p.C2115W | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CUX1 | c.3613G>T p.E1205* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- CX3CL1 | c.1136G>A p.G379D | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP3A43 | c.766A>G p.M256V | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, varscan2
- CYP4B1 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- DACH2 | c.1486_1487dup p.I497Kfs*24 | Frame Shift Ins (INS) | VAF 24/119 reads (20%) | called by mutect2, varscan2
- DARS1 | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DARS2 | c.1429T>C p.S477P | Missense Mutation (SNP) | VAF 116/647 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- DCAF15 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 78/245 reads (32%) | called by muse, mutect2, varscan2
- DCD | c.204del p.G69Afs*2 | Frame Shift Del (DEL) | VAF 99/388 reads (26%) | called by mutect2, pindel, varscan2
- DCHS1 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.085); called by muse, varscan2
- DDO | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 32/122 reads (26%) | called by muse, mutect2, varscan2
- DDX59 | c.1595A>G p.Q532R | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DDX59 | c.1289del p.K430Rfs*8 | Frame Shift Del (DEL) | VAF 36/178 reads (20%) | called by mutect2, pindel
- DDX59 | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 42/295 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DENND1B | c.366+2T>C p.X122_splice | Splice Site (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- DENND4A | c.4968T>G p.D1656E | Missense Mutation (SNP) | VAF 12/271 reads (4%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); called by muse, mutect2
- DISC1 | c.694T>C p.S232P | Missense Mutation (SNP) | VAF 110/709 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DISP2 | c.390del p.S131Hfs*34 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel
- DMD | c.8625G>T p.E2875D | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DMD | c.4379T>C p.L1460S | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DMWD | c.596del p.K199Rfs*12 | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | called by mutect2, pindel
- DNAH5 | c.8540T>C p.L2847S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2
- DNAH5 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 19/458 reads (4%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2
- DNM2 | c.2377del p.L793* (on ENST00000355667 / NM_001005360.3; = p.L789* on NM_004945.3) | Frame Shift Del (DEL) | VAF 59/226 reads (26%) | called by mutect2, pindel, varscan2
- DOCK6 | c.5620A>G p.T1874A | Missense Mutation (SNP) | VAF 14/385 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2
- DPH2 | c.1344A>G p.A448= | Splice Region (SNP) | VAF 36/98 reads (37%) | called by muse, mutect2, varscan2
- DPP9 | c.595G>A p.A199T (on ENST00000598800; = p.A228T on NM_139159.5) | Missense Mutation (SNP) | VAF 93/370 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- DPPA4 | c.766T>C p.W256R | Missense Mutation (SNP) | VAF 121/319 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPYS | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 13/365 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DRC3 | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- DUSP5 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 138/425 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- DYNC1H1 | c.4457T>C p.L1486S | Missense Mutation (SNP) | VAF 19/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DYNC1H1 | c.10850A>G p.D3617G | Missense Mutation (SNP) | VAF 21/557 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); called by muse, mutect2
- ECEL1 | c.457A>T p.I153F | Missense Mutation (SNP) | VAF 113/316 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- EGF | c.3160del p.A1054Pfs*25 | Frame Shift Del (DEL) | VAF 117/452 reads (26%) | called by mutect2, pindel, varscan2
- EIF2A | c.1609del p.I537Sfs*4 | Frame Shift Del (DEL) | VAF 62/201 reads (31%) | called by mutect2, pindel, varscan2
- EIF3G | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 102/265 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF4B | c.1648G>T p.G550* | Nonsense Mutation (SNP) | VAF 46/203 reads (23%) | called by muse, mutect2, varscan2
- EIF5A | c.41C>G p.A14G | Missense Mutation (SNP) | VAF 28/620 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- EMP1 | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 117/404 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ENOX1 | c.369del p.P124Lfs*79 | Frame Shift Del (DEL) | VAF 24/182 reads (13%) | called by mutect2, pindel, varscan2
- ENTPD2 | c.1475C>A p.P492Q (on ENST00000355097 / NM_203468.3; = p.P469Q on NM_001246.4) | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- EP300 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 125/408 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- EP300 | c.4626G>T p.K1542N | Missense Mutation (SNP) | VAF 8/205 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.852); called by muse, mutect2
- EP400 | c.8554-5T>C | Splice Region (SNP) | VAF 107/346 reads (31%) | called by muse, mutect2, varscan2
- EPHA7 | c.2888T>C p.V963A | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2
- EPHX3 | c.1033dup p.Q345Pfs*58 | Frame Shift Ins (INS) | VAF 128/413 reads (31%) | called by mutect2, pindel, varscan2
- EPS15L1 | c.2221T>G p.F741V | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ERVMER34-1 | c.147T>G p.H49Q | Missense Mutation (SNP) | VAF 113/340 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.08); called by muse, mutect2
- EXTL1 | c.1163del p.P388Qfs*35 | Frame Shift Del (DEL) | VAF 77/291 reads (26%) | called by mutect2, pindel, varscan2
- EYA4 | c.1726A>G p.I576V (on ENST00000531901 / NM_001301013.1; = p.I570V on NM_004100.5) | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- FAM155A | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 33/292 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, varscan2
- FAT3 | c.5404G>T p.D1802Y | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAT4 | c.2612del p.G871Afs*3 | Frame Shift Del (DEL) | VAF 37/136 reads (27%) | called by mutect2, pindel, varscan2
- FBLN1 | c.185+2T>C p.X62_splice | Splice Site (SNP) | VAF 194/561 reads (35%) | called by muse, mutect2, varscan2
- FBLN7 | c.839T>G p.V280G | Missense Mutation (SNP) | VAF 101/275 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- FBXO10 | c.2461A>G p.I821V | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- FBXW9 | c.251dup p.E85Gfs*32 | Frame Shift Ins (INS) | VAF 132/473 reads (28%) | called by mutect2, pindel, varscan2
- FCGBP | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 34/115 reads (30%) | called by muse, mutect2, varscan2
- FCRL5 | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 99/499 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- FCSK | c.1900T>C p.W634R | Missense Mutation (SNP) | VAF 15/294 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FERMT3 | c.1295T>C p.M432T (on ENST00000279227 / NM_178443.3; = p.M428T on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.17); called by muse, mutect2
- FGF19 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 138/432 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- FILIP1L | c.1223T>C p.L408S (on ENST00000354552 / NM_182909.3; = p.L168S on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FKBP4 | c.542A>C p.K181T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FKBP6 | c.386del p.P129Qfs*40 | Frame Shift Del (DEL) | VAF 190/694 reads (27%) | called by mutect2, pindel, varscan2
- FLCN | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 28/626 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.41); called by muse, mutect2
- FLG2 | c.7171C>T p.H2391Y | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by mutect2, varscan2
- FMN1 | c.3096del p.K1032Nfs*31 (on ENST00000616417 / NM_001277313.2; = p.K809Nfs*31 on NM_001103184.4) | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- FMO1 | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- FNDC1 | c.5471G>T p.S1824I | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- FOXD4L6 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 101/836 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, varscan2
- FRAS1 | c.3902A>T p.D1301V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FYB2 | c.1851del p.E618Rfs*24 | Frame Shift Del (DEL) | VAF 32/95 reads (34%) | called by mutect2, varscan2
- GAA | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 177/545 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- GABRB3 | c.508del p.L170Wfs*66 | Frame Shift Del (DEL) | VAF 124/455 reads (27%) | called by mutect2, pindel, varscan2
- GABRD | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 159/577 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRP | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GABRR1 | c.857T>C p.L286P | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAGE12J | c.4A>G p.S2G | Missense Mutation (SNP) | VAF 78/1141 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.742); called by muse, mutect2
- GALR3 | c.496T>C p.Y166H | Missense Mutation (SNP) | VAF 8/239 reads (3%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.876); called by muse, mutect2
- GAPVD1 | c.3955C>T p.R1319* (on ENST00000394104; = p.R1328* on NM_015635.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/316 reads (3%) | called by muse, mutect2
- GATA6 | c.521C>A p.A174D | Missense Mutation (SNP) | VAF 27/360 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2
- GDE1 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GDF7 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- GDPD2 | c.1439A>G p.Y480C | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.258); called by muse, mutect2
- GFOD1 | c.743A>C p.D248A | Missense Mutation (SNP) | VAF 96/318 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GJA3 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 120/385 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GK | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 20/542 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2
- GLCCI1 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GLIPR1L2 | c.562T>A p.F188I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GNPTAB | c.2675T>C p.L892S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GOLGA8R | c.1306del p.E436Rfs*20 | Frame Shift Del (DEL) | VAF 44/242 reads (18%) | called by pindel, varscan2
- GOLIM4 | c.782T>C p.V261A | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GOLM1 | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GP5 | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 139/469 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- GPCPD1 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GPR132 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- GPRC5B | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 162/513 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRB10 | c.1602T>A p.C534* (on ENST00000398812; = p.C488* on NM_001001549.3) | Nonsense Mutation (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- GREB1L | c.4615G>A p.E1539K | Missense Mutation (SNP) | VAF 30/473 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.54); called by muse, mutect2
- GRIP1 | c.1121A>G p.H374R | Missense Mutation (SNP) | VAF 18/458 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.084); called by muse, mutect2
- GRM1 | c.197A>C p.K66T | Missense Mutation (SNP) | VAF 133/387 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GSTM3 | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GTF3C3 | c.2101C>T p.Q701* | Nonsense Mutation (SNP) | VAF 57/198 reads (29%) | called by muse, mutect2, varscan2
- GUCY1A1 | c.1719G>A p.M573I | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2
- GUCY2D | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HAO2 | c.291dup p.A98Sfs*15 | Frame Shift Ins (INS) | VAF 28/72 reads (39%) | called by mutect2, pindel, varscan2
- HCN3 | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 164/1152 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HCRTR2 | c.86del p.L29* | Frame Shift Del (DEL) | VAF 199/665 reads (30%) | called by mutect2, pindel, varscan2
- HECTD4 | c.7285G>A p.D2429N | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HEPH | c.47T>C p.L16S (on ENST00000343002; = p.L70S on NM_138737.5) | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- HERC1 | c.2992G>A p.A998T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HERC2 | c.10235C>T p.A3412V | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.011); called by muse, mutect2
- HHIP | c.383_386del p.R128Kfs*7 | Frame Shift Del (DEL) | VAF 49/193 reads (25%) | called by mutect2, pindel, varscan2
- HMCN2 | c.10500G>T p.E3500D | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HMCN2 | c.13658G>A p.G4553D | Missense Mutation (SNP) | VAF 22/536 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.245); called by muse, mutect2
- HOXD4 | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 20/510 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.445); called by muse, mutect2
- HS6ST1 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 128/515 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- HSPB2 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 26/603 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.73); called by muse, mutect2
- HTATSF1 | c.1506G>C p.E502D | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- HTT | c.2096del p.N699Mfs*9 | Frame Shift Del (DEL) | VAF 70/226 reads (31%) | called by mutect2, varscan2
- HYKK | c.157T>C p.S53P | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2
- IDO2 | c.1066A>G p.I356V (on ENST00000389060; = p.I369V on NM_194294.2) | Missense Mutation (SNP) | VAF 128/328 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IGHMBP2 | c.729del p.S244Pfs*41 | Frame Shift Del (DEL) | VAF 151/540 reads (28%) | called by mutect2, pindel, varscan2
- IGHV1-58 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 34/680 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2
- IGHV3-33 | c.165G>T p.W55C | Missense Mutation (SNP) | VAF 122/452 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGSF11 | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF3 | c.35C>A p.A12D | Missense Mutation (SNP) | VAF 134/431 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- IKZF5 | c.15del p.K5Nfs*8 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | called by mutect2, varscan2
- IL16 | c.437G>A p.C146Y | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- INA | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 119/330 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
815 further variants in this file (342 protein-altering or splice-affecting, 279 silent, 194 other) are not listed here.
